Gene-level copy-number profile of tumor specimen TARGET-20-PARCEV-09A from TARGET case TARGET-20-PARCEV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.4 years (4,152 days).
Specimen TARGET-20-PARCEV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.7f2e6e4b-b77a-5bd0-90b1-38025d01297e.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PARCEV-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 388 have no estimate.
https://portal.gdc.cancer.gov/files/8d4d90df-726c-442b-981b-8eb1fca7e415

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 936; copy number 1: 4,163; copy number 2: 46,564; copy number 3: 5,308; copy number 4: 1,698; copy number 5: 1,262; copy number 6: 127; copy number 7: 139; copy number 8: 24; copy number 10: 1; copy number 17: 13.

Homozygous deletions (total copy number 0; autosomes only): 413 genes in 99 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:6,615,389–6,770,311, 4 genes (within-gene range 0–2): MIR7515HG, AC097517.1, MIR7515, LINC00487.
- chr2:21,687,430–23,199,056, 10 genes: LINC01822, RN7SL117P, AC096570.1, AC068044.1, AC099799.1, RNA5SP87, LINC01830, LINC01884, RN7SKP27, AC018467.1.
- chr2:29,192,774–29,921,586, 3 genes (within-gene range 0–2): ALK, AC074096.1, RN7SL516P.
- chr2:80,028,012–81,201,184, 6 genes: AC016716.1, RBM7P1, LRRTM1, AC008067.1, AC012355.1, ANKRD11P1.
- chr2:84,031,140–84,040,720, 2 genes: CRLF3P3, ST6GALNAC2P1.
- chr2:108,049,200–108,099,492, 2 genes: LINC01593, ACTP1.
- chr3:139,935,185–140,577,397, 4 genes (within-gene range 0–2): CLSTN2, AC010181.1, AC010181.2, CLSTN2-AS1.
- chr4:10,199,823–10,295,579, 8 genes: AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2, AC006499.3, AC006499.5, AC006499.7.
- chr4:151,949,338–152,178,573, 7 genes: AC097375.4, AC097375.3, RNA5SP169, AC097375.5, LINC02273, AC079340.3, AC079340.1.
- chr5:88,381,957–88,383,260, 3 genes: RPS3AP22, SNORA70, AC091826.1.
- chr5:168,993,000–170,083,382, 10 genes: AC011389.1, AC011389.2, SLIT3-AS1, MIR585, RNU6-477P, SPDL1, DOCK2, AC008680.1, INSYN2B, MIR378E.
- chr6:14,280,127–14,502,701, 4 genes: LINC01108, AL080313.2, AL080313.1, AL009177.1.
- chr6:85,949,690–86,087,134, 3 genes: AL450338.2, RNU4-12P, RPL7P27.
- chr7:36,781,008–36,841,373, 3 genes: AC007349.3, NPM1P18, AC007349.2.
- chr9:114,784,652–120,245,050, 41 genes (within-gene range 0–2): TNFSF15, AL133412.1, DELEC1, TNFSF8, TNC, AL162425.1, AL355601.1, AL691420.1, U2, LINC00474, AL691426.1, PAPPA, PAPPA-AS2, AL137024.1, PAPPA-AS1, ASTN2, ASTN2-AS1, AL133284.1, TRIM32, AL157829.1, RPL10P3, SNORA70C, RN7SKP128, RN7SKP125, AL445644.1, AL161630.1, RPL35AP22, AL160272.2, TLR4, RNU6-1082P, AL160272.1, AL354754.1, TPT1P9, AL355592.1, LINC02578, TUBB4BP6, BRINP1, AC006288.1, LINC01613, AL441989.1, MIR147A.
- chr10:33,759,713–33,864,723, 2 genes: LINC00838, RPL23P11.
- chr10:76,869,601–77,638,369, 4 genes (within-gene range 0–2): KCNMA1, KCNMA1-AS1, KCNMA1-AS2, AL731575.1.
- chr10:94,278,681–94,315,327, 2 genes: PLCE1-AS1, AL139124.1.
- chr10:104,566,931–105,904,771, 8 genes: AL161646.1, SORCS3, SORCS3-AS1, RNU6-463P, PPIAP38, YWHAZP5, LINC02627, AL731574.1.
- chr11:5,689,697–5,738,523, 4 genes (within-gene range 0–8): TRIM22, OR52U1P, OR52P1P, OR56B1.
- chr11:80,957,317–81,040,236, 2 genes: AP003398.1, AP003398.2.
- chr12:13,196,723–13,982,002, 10 genes (within-gene range 0–2): EMP1, AC022276.1, LINC01559, GRIN2B, RNA5SP353, RNU6-590P, AC007527.1, AC007527.2, AC007535.1, RN7SKP162.
- chr12:28,505,394–28,978,685, 4 genes: RNA5SP355, AC084754.1, AC022081.1, AC024255.1.
- chr12:42,687,195–43,163,110, 6 genes: LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461.
- chr12:66,950,754–67,590,771, 10 genes (within-gene range 0–2): AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408.
- chr12:91,871,122–91,906,187, 3 genes: AC090049.2, LINC02404, AC090049.1.
- chr12:114,077,133–114,113,489, 4 genes: AC010183.1, AC010183.2, HAUS8P1, GLULP5.
- chr14:21,811,502–21,918,756, 11 genes: TRAV9-1, TRAV10, TRAV11, TRAV12-1, TRAV8-2, TRAV8-3, TRAV13-1, TRAV12-2, TRAV8-4, TRAV8-5, TRAV13-2.
- chr15:47,359,430–48,142,672, 10 genes (within-gene range 0–2): AC023905.1, AC009558.1, AC009558.2, AC012050.1, AC044787.1, LINC01491, AC092078.2, AC092078.1, AC092078.3, SLC24A5.
- chr15:85,958,717–87,703,852, 15 genes: AC104229.1, LINC01584, AGBL1, RNA5SP400, AC016180.2, AC016180.1, AGBL1-AS1, AC012229.1, AC016987.2, AC016987.1, AC078905.1, AC020687.1, RNU6-185P, LINC00052, AC103871.1.
- chr16:25,691,959–26,137,685, 2 genes (within-gene range 0–1): HS3ST4, AC093516.1.
- chr16:26,025,237–26,729,126, 9 genes: MIR548W, RNA5SP405, HMGN2P3, HSPE1P16, AC009158.1, AC130464.1, AC002331.1, LINC02195, AC009035.1.
- chr16:52,078,622–52,099,120, 4 genes: AC009039.1, AC009039.2, LINC00919, LINC02180.
- chr16:64,364,781–65,938,453, 13 genes (within-gene range 0–2): AC092131.1, PPIAP48, AC009101.1, CDH11, AC010533.1, LINC02126, AC009055.2, AC009055.1, LINC00922, AC092138.2, AC092138.1, AC022164.1, AC025281.1.
- chr17:33,529,787–34,859,046, 33 genes: AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4, AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1, AC022903.1.
- chr17:51,312,609–52,535,701, 8 genes: LINC02071, AC005823.2, AC005823.1, LINC02073, RPL7P48, CA10, AC002090.1, LINC01982.
- chr20:11,234,170–11,345,855, 2 genes: AL049649.1, RPS11P1.
- chr20:39,213,777–43,189,970, 40 genes (within-gene range 0–2): LINC01734, AL035251.1, ATG3P1, RN7SL680P, AL132981.1, AL118523.1, HSPE1P1, LINC01370, AL133419.1, AL009050.1, MAFB, AL035665.1, AL035665.2, RNA5SP484, RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1, LPIN3, EMILIN3, AL031667.1, CHD6, AL031667.2, AL031667.3, RPL12P11, RNU6-1018P, AL133229.1, AL049812.2, AL049812.1, AL049812.3, PTPRT, AL035666.1, AL031656.1, PTPRT-AS1.
- chr20:52,192,159–52,890,386, 9 genes (within-gene range 0–2): LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1.
- chr22:33,162,226–35,002,862, 16 genes (within-gene range 0–2): LARGE1, Z82198.2, Z82173.1, MIR4764, SNORA50B, Z69713.1, LARGE-IT1, LARGE-AS1, Z73429.1, LINC01643, Z68323.1, AL021877.1, AL021877.2, Z82196.1, Z82196.2, LINC02885.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,558 genes in 50 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,902,795–148,288,951, 19 genes, copy number 7: GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1, NBPF11, PFN1P4, ABHD17AP1, LINC02805, AC239809.3, RNA5SP57, AC239809.1, AC239809.2, RNVU1-22, LINC01731, AC245100.3.
- chr1:148,295,180–148,344,638, 4 genes, copy number 7 (within-gene range 2–7): LINC02806, AC245100.1, AC245100.5, Y_RNA.
- chr2:38,814–578,145, 15 genes, copy number 5–6: FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1.
- chr2:88,811,186–88,861,563, 1 gene, copy number 17 (within-gene range 2–17): AC244205.1.
- chr2:88,857,161–88,947,957, 12 genes, copy number 17: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5.
- chr2:103,362,082–103,403,712, 1 gene, copy number 8: AC011593.1.
- chr2:131,555,007–131,649,615, 5 genes, copy number 5: AC093838.1, POTEKP, RNU6-617P, LINC01087, GRAMD4P8.
- chr2:186,486,253–186,695,287, 4 genes, copy number 5 (within-gene range 3–5): ZC3H15, DPRXP1, ITGAV, AC017101.1.
- chr2:211,535,653–211,535,769, 1 gene, copy number 6: RNA5SP119.
- chr3:197,889,077–198,222,513, 13 genes, copy number 5–6 (within-gene range 2–6): IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr4:153,710,160–153,789,083, 3 genes, copy number 6 (within-gene range 2–6): RNF175, AC020703.1, SFRP2.
- chr4:187,942,164–189,002,075, 21 genes, copy number 5 (within-gene range 5–6): AC108073.3, AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1, LINC01060, AC093909.3, AC093909.5, RNU7-192P, AC093909.1, AC093909.6, AC093909.2, LINC02508, AC093909.4, AC122138.1.
- chr4:189,288,677–190,092,279, 28 genes, copy number 5: AC105924.1, HSP90AA4P, LINC01262, AF250324.1, RNU1-51P, FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr5:26,711,551–26,749,997, 2 genes, copy number 7: AC113347.4, CCNB3P1.
- chr6:655,939–796,781, 7 genes, copy number 6 (within-gene range 2–6): HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1.
- chr6:25,882,026–29,077,168, 197 genes, copy number 5 (broad region; genes not listed).
- chr6:46,758,296–46,839,782, 2 genes, copy number 5: AL161618.1, MEP1A.
- chr6:73,241,314–73,395,133, 11 genes, copy number 6 (within-gene range 2–6): KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3.
- chr7:13,891,229–14,010,763, 2 genes, copy number 6–10: ETV1, Y_RNA.
- chr7:23,562,459–23,832,513, 9 genes, copy number 6 (within-gene range 2–6): AC006026.1, CLK2P1, CCDC126, FCF1P1, AC006026.2, FAM221A, AC006026.3, STK31, PCMTD1P3.
- chr8:150,584–5,142,707, 69 genes, copy number 5–8 (broad region; genes not listed).
- chr8:5,659,679–18,223,689, 359 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr8:30,027,713–31,220,984, 37 genes, copy number 5: MAP2K1P1, RNU6-1218P, SARAF, AC044849.1, LEPROTL1, RPS15AP24, MBOAT4, AC026979.2, DCTN6, AC026979.1, AC026979.4, AC026979.3, HSPA8P11, AC090820.1, AC090820.2, AC109329.1, PPIAP84, TUBBP1, RBPMS-AS1, RBPMS, AC102945.2, GTF2E2, AC102945.1, SMIM18, RNU5A-3P, GSR, UBXN8, HIKESHIP3, PPP2CB, TEX15, AC090281.1, AC008066.1, PURG, WRN, SUMO2P16, AC009563.1, KCTD9P6.
- chr8:37,695,782–71,592,025, 541 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr9:27,524,314–27,610,745, 4 genes, copy number 6: IFNK, AL451123.1, C9orf72, CTAGE12P.
- chr9:38,643,042–41,701,096, 88 genes, copy number 5–6 (broad region; genes not listed).
- chr10:81,870,778–81,875,133, 1 gene, copy number 5: AL096706.1.
- chr10:94,333,226–94,362,959, 1 gene, copy number 5: NOC3L.
- chr10:129,693,722–129,702,117, 1 gene, copy number 6: AL157832.2.
- chr12:30,086,342–30,217,916, 3 genes, copy number 7 (within-gene range 1–7): AC023511.3, AC023511.2, AC023511.1.
- chr13:22,589,699–22,706,206, 3 genes, copy number 6–8: AL512484.1, FTH1P7, DDX39AP1.
- chr15:26,851,132–26,851,610, 1 gene, copy number 8: AC135999.1.
- chr17:41,026,026–41,440,983, 47 genes, copy number 7: KRTAP1-5, KRTAP1-4, KRTAP1-3, KRTAP1-1, KRTAP2-1, KRTAP2-2, KRTAP2-3, KRTAP2-4, KRTAP2-5P, KRTAP4-7, AC100808.1, KRTAP4-8, KRTAP4-16, KRTAP4-9, KRTAP4-11, KRTAP4-12, KRTAP4-6, KRTAP4-5, KRTAP4-4, KRTAP4-3, KRTAP4-2, KRTAP4-1, KRTAP4-17P, KRTAP9-1, KRTAP9-12P, KRTAP9-2, KRTAP9-3, KRTAP9-8, KRTAP9-4, KRTAP9-9, KRTAP9-6, KRTAP9-11P, KRTAP9-7, KRTAP9-10P, KRTAP29-1, KRTAP16-1, KRTAP17-1, TBC1D3P7, AC003958.1, KRT33A, KRT33B, KRT34, KRT31, AC003958.2, KRT41P, KRT37, KRT38.
- chr18:63,949,301–63,981,774, 2 genes, copy number 5 (within-gene range 5–7): HMSD, AC009802.1.
- chr18:67,375,133–67,375,305, 1 gene, copy number 5: AC091042.1.
- chr19:20,122,569–20,321,305, 1 gene, copy number 8 (within-gene range 2–8): AC011447.3.
- chr19:20,167,214–20,331,517, 12 genes, copy number 8 (within-gene range 2–8): ZNF486, BNIP3P16, AC011447.4, AC011447.6, AC011447.7, BNIP3P17, AC078899.3, AC078899.1, BNIP3P18, AC078899.4, BNIP3P19, AC078899.5.
- chr19:20,351,502–20,352,079, 1 gene, copy number 8: BNIP3P20.
- chr19:53,235,381–53,291,426, 7 genes, copy number 7: ZNF677, AC092070.3, VN1R2, VN1R4, AC092070.4, FAM90A27P, BIRC8.
- chr19:57,435,325–57,559,863, 12 genes, copy number 5 (within-gene range 3–5): ZNF749, AC004076.1, AC004076.2, VN1R1, VN1R107P, ZNF772, AC003005.2, ZNF419, AC003005.1, ZNF773, ZNF549, ZNF550.

Autosomal genes at a single copy (total copy number 1): 3,911. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
